Somatic mutation profile of tumor specimen TCGA-AH-6549-01A (aliquot TCGA-AH-6549-01A-11D-1826-10) from TCGA case TCGA-AH-6549, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 66.6 years (24,337 days).
Specimen TCGA-AH-6549-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edfddbf6-81b3-4973-9f5e-8c7c34c5b587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AH-6549-10A (Blood Derived Normal), aliquot TCGA-AH-6549-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6731908-cf40-4ac6-9ee3-fc92b2c274d4

The open-access MAF lists 91 somatic variants for this specimen: 63 protein-altering or splice-affecting, 28 silent.
By variant classification: Missense Mutation 56, Silent 28, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 59/136 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 42/55 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.1459A>G p.K487E | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99950239; called by muse, mutect2, varscan2
- ATP10A | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1317398516, COSV100791329; called by muse, mutect2, varscan2
- ATRX | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV64882760; called by muse, mutect2, varscan2
- C14orf39 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 75/114 reads (66%) | catalogued as COSV100408223, COSV58780369; called by muse, mutect2, varscan2
- CATSPER1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as rs543744984, COSV56408716; called by muse, mutect2, varscan2
- CLTCL1 | c.2730G>T p.E910D | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54228414; called by muse, mutect2, varscan2
- CNNM4 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100998876; called by muse, mutect2, varscan2
- CNTN4 | c.1054A>C p.N352H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100639832, COSV61867047; called by muse, mutect2, varscan2
- CSMD3 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.078); catalogued as COSV52183615, COSV99852000; called by muse, mutect2, varscan2
- CSMD3 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52096184, COSV52158214; called by muse, mutect2, varscan2
- CYTH4 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1267923967, COSV50634162; called by muse, mutect2, varscan2
- DFFA | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100986718; called by muse, mutect2, varscan2
- DOCK1 | c.2740G>T p.V914L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV54736293; called by muse, mutect2, varscan2
- FAT1 | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.242); catalogued as COSV71673356; called by muse, mutect2, varscan2
- FBXW7 | c.1697G>T p.W566L (on ENST00000281708 / NM_001349798.2; = p.W486L on NM_018315.5) | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949515, COSV99662097; called by muse, mutect2, varscan2
- FNDC1 | c.2616C>A p.S872R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99797446; called by muse, mutect2, varscan2
- FOXP4 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.093); catalogued as COSV57223135; called by muse, mutect2, varscan2
- FOXR2 | c.224A>T p.E75V | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV59258889; called by muse, mutect2, varscan2
- FREM2 | c.9090A>T p.R3030S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99751636; called by muse, mutect2, varscan2
- FRMPD1 | c.1501C>G p.L501V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV100899694; called by muse, mutect2, varscan2
- GRIA2 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52383728; called by muse, mutect2, varscan2
- GRM7 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs952338137, COSV63143156; called by muse, mutect2, varscan2
- HOXC11 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs771475169, COSV54533942, COSV99678583; called by muse, mutect2, varscan2
- ICE1 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV56822501; called by muse, mutect2, varscan2
- INTS4 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265086812, COSV71087127; called by muse, mutect2, varscan2
- ITPR1 | c.6325G>A p.A2109T (on ENST00000354582; = p.A2054T on NM_002222.7) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373973399, COSV56967721; called by muse, mutect2, varscan2
- KBTBD8 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as rs762347428, COSV55126318, COSV55127130; called by muse, mutect2, varscan2
- KIAA0100 | c.1627T>C p.S543P | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV101197453; called by muse, mutect2, varscan2
- KRT222 | c.121dup p.M41Nfs*5 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | catalogued as rs748510701; called by mutect2, varscan2
- L1CAM | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as rs1557092299, CM981152, COSV62829360; called by muse, mutect2, varscan2
- MLNR | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54534216; called by mutect2, varscan2
- MYT1L | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1240453695, COSV101221591; called by muse, mutect2
- NALCN | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51943427; called by muse, mutect2, varscan2
- NBEA | c.8167G>A p.V2723I | Missense Mutation (SNP) | VAF 111/181 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV100085211; called by muse, mutect2, varscan2
- NFE2L3 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV50231756; called by muse, mutect2, varscan2
- NLRC3 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762715807, COSV57088485; called by muse, mutect2, varscan2
- OPRK1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs202165724, COSV55570192; called by muse, mutect2, varscan2
- PASD1 | c.1639A>T p.K547* | Nonsense Mutation (SNP) | VAF 51/178 reads (29%) | catalogued as COSV100949739; called by muse, mutect2, varscan2
- PDE1A | c.1216T>C p.C406R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59520457; called by muse, mutect2
- PRKCB | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100335818; called by muse, mutect2, varscan2
- RAPGEF2 | c.2771G>A p.R924Q | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT tolerated (0.09); PolyPhen benign (0.336); catalogued as rs201720107; called by muse, mutect2, varscan2
- RFX1 | c.2206G>T p.V736L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV54327506; called by muse, mutect2, varscan2
- RSPH4A | c.1823C>G p.T608R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99994351; called by muse, mutect2, varscan2
- SETD2 | c.5233A>G p.I1745V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as COSV100340332; called by muse, mutect2, varscan2
- SEZ6L2 | c.2390T>G p.F797C (on ENST00000308713 / NM_001114099.3; = p.F727C on NM_012410.4) | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100435996; called by muse, mutect2, varscan2
- SLITRK4 | c.422A>G p.N141S | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567589; called by muse, mutect2, varscan2
- SPICE1 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.218); catalogued as rs778028245, COSV99871957; called by muse, mutect2, varscan2
- TCTE1 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV65255400; called by muse, mutect2, varscan2
- TCTN2 | c.1706T>C p.L569P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100315468; called by muse, mutect2, varscan2
- TENM3 | c.5644G>A p.E1882K | Missense Mutation (SNP) | VAF 48/63 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs775010852, COSV69306263; called by muse, mutect2, varscan2
- TPTE2 | c.743A>T p.E248V (on ENST00000400230 / NM_199254.2; = p.E171V on NM_130785.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV55019641; called by muse, mutect2, varscan2
- TRIML2 | c.669T>A p.H223Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100456459; called by muse, mutect2, varscan2
- TRPC4 | c.467A>T p.E156V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58996985; called by muse, mutect2, varscan2
- TSKU | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100290291; called by muse, mutect2, varscan2
- TTC3 | c.2536C>T p.L846F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV100696192; called by muse, mutect2, varscan2
- UBQLNL | c.702G>T p.M234I | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100975783; called by muse, mutect2, varscan2
- WDR6 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs546787787, COSV58244986; called by muse, mutect2, varscan2
- ZNF160 | c.2324G>T p.S775I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.892); catalogued as COSV100762203, COSV100762528; called by muse, mutect2, varscan2
- APC | c.4483del p.S1495Vfs*12 | Frame Shift Del (DEL) | VAF 36/62 reads (58%) | called by mutect2, pindel, varscan2
- NFRKB | c.3566_3567del p.S1189Cfs*42 (on ENST00000446488 / NM_001143835.2; = p.S1214Cfs*42 on NM_006165.3) | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by pindel, varscan2
- UACA | c.101_102del p.Y34* | Frame Shift Del (DEL) | VAF 45/93 reads (48%) | called by pindel, varscan2
- ARMH4 | c.1335T>G p.S445= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV50762911; called by muse, mutect2
- BSND | c.507C>T p.D169= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as rs749127391, COSV100987669; called by muse, mutect2, varscan2
- CHD5 | c.4896G>A p.P1632= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as rs758058613, COSV99315576; called by muse, mutect2, varscan2
- EVPL | c.4041G>A p.A1347= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1245902672, COSV56908923; called by muse, mutect2, varscan2
- FLG2 | c.1362C>A p.G454= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as COSV66171175; called by muse, mutect2, varscan2
- FLT4 | c.2940C>T p.V980= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99989611; called by muse, mutect2, varscan2
- HAPLN4 | c.114C>T p.H38= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV52268623; called by muse, mutect2, varscan2
- HBD | c.423C>T p.A141= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV53082366; called by muse, mutect2, varscan2
- HSPA12A | c.873C>A p.T291= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1275638957, COSV100980027; called by muse, mutect2, varscan2
- IFI16 | c.2226G>A p.P742= (on ENST00000295809 / NM_001364867.2; = p.P686= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1334734836, COSV99858219; called by muse, mutect2, varscan2
- IGSF22 | c.1974C>T p.R658= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs369745010; called by muse, mutect2, varscan2
- KANSL2 | c.72A>G p.E24= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100771071; called by muse, mutect2, varscan2
- KCNA2 | c.630C>T p.I210= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as rs761112803, COSV60371855; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCND2 | c.72G>A p.S24= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs771647361, COSV100479327; called by muse, mutect2, varscan2
- KIF17 | c.828G>A p.A276= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs1290236679, COSV56116505; called by muse, mutect2, varscan2
- LTF | c.2079G>A p.L693= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV99212241; called by muse, mutect2, varscan2
- NQO2 | c.88C>T p.L30= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100583288; called by muse, mutect2, varscan2
- PAPLN | c.2685C>T p.A895= (on ENST00000554301; = p.A868= on NM_173462.4) | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs755404435, COSV99390638; called by muse, mutect2, varscan2
- PCDHA12 | c.1776G>A p.A592= | Silent (SNP) | VAF 281/339 reads (83%) | catalogued as COSV56488016; called by muse, mutect2, varscan2
- PCDHGA10 | c.1494C>T p.D498= | Silent (SNP) | VAF 57/71 reads (80%) | catalogued as COSV53928905; called by muse, mutect2, varscan2
- RAB4A | c.429A>G p.R143= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100797116; called by muse, mutect2, varscan2
- RSPH4A | c.1425T>C p.P475= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs1186602025, COSV99994349; called by muse, mutect2
- RYR1 | c.5322G>A p.P1774= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs572516017, COSV100614582; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLC9A5 | c.2097C>T p.T699= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as rs372783358, COSV55361477; called by muse, mutect2, varscan2
- SMO | c.1084C>T p.L362= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV99977253; called by muse, mutect2, varscan2
- TOGARAM2 | c.2568C>G p.L856= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs770260391, COSV65420933, COSV65424294; called by muse, mutect2, varscan2
- TSHZ3 | c.2298G>A p.P766= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs368908849, COSV53672099; called by muse, mutect2, varscan2
- ZNF568 | c.1497G>A p.E499= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100451488; called by muse, mutect2, varscan2
